Gene-level copy-number profile of tumor specimen MP2PRT-PATAHM-TMP1-A from MP2PRT case MP2PRT-PATAHM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,737 days).
Specimen MP2PRT-PATAHM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a458ec81-e3c1-412a-92b7-e8866f741eb6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATAHM-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/220f80eb-df9c-474d-8190-6055d2572812

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 152; copy number 1: 82; copy number 2: 38,810; copy number 3: 18,605; copy number 4: 746.

Homozygous deletions (total copy number 0; autosomes only): 152 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,234,174–89,254,015, 4 genes (within-gene range 0–1): IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,989,987–89,990,221, 1 gene: IGKV3D-25.
- chr2:113,325,372–113,425,548, 2 genes: AC016745.1, IGKV1OR2-108.
- chr7:38,239,580–38,350,022, 18 genes (within-gene range 0–2): TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRGV5P, TRGV5.
- chr14:105,672,308–106,481,706, 125 genes (within-gene range 0–3) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–3): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 82. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
